Gene-level copy-number profile of tumor specimen TCGA-MY-A5BD-01A from TCGA case TCGA-MY-A5BD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 62.7 years (22,901 days).
Specimen TCGA-MY-A5BD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.79f5965d-61e9-4225-a192-878f5d1ebe6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MY-A5BD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9a732f3f-c238-4c36-b4af-eabee604fcc1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,878; copy number 2: 49,545; copy number 3: 5,405; copy number 4: 9; copy number 7: 937; copy number 9: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MY-A5BD-01A-11D-A26F-01): tumor purity 0.94, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 982 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,855,739–198,222,513, 937 genes, copy number 7 (broad region; genes not listed).
- chr19:44,501,677–45,305,284, 45 genes, copy number 9 (within-gene range 1–9): CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1, RELB, CLASRP, RNU6-611P, ZNF296, GEMIN7-AS1, GEMIN7, MARK4, PPP1R37, EIF5AP3, AC005757.1, NKPD1, TRAPPC6A, BLOC1S3, EXOC3L2.

Autosomal genes at a single copy (total copy number 1): 3,878. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
